Somatic mutation profile of tumor specimen MP2PRT-PATYNT-TMP1-A (aliquot MP2PRT-PATYNT-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATYNT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (737 days).
Specimen MP2PRT-PATYNT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b784c304-c44f-4e60-bf4c-98a1de52a61a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYNT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYNT-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76b7d598-345b-48af-94e6-13fef63e3046

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNA2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 229/565 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs750100538; called by muse, mutect2, varscan2
- DMBT1 | c.5905A>T p.I1969F (on ENST00000338354 / NM_001377530.1; = p.I1212F on NM_004406.3) | Missense Mutation (SNP) | VAF 199/438 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.976); catalogued as COSV57562614; called by muse, mutect2, varscan2
- FNDC1 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 260/551 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs757273488, COSV99794990; called by muse, mutect2, varscan2
- POLA1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 264/653 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RNF224 | c.87_99del p.A30Pfs*51 | Frame Shift Del (DEL) | VAF 213/761 reads (28%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2085G>A p.P695= (on ENST00000389672 / NM_001080448.3; = p.P87= on NM_173655.4) | Silent (SNP) | VAF 98/279 reads (35%) | catalogued as rs138510905, COSV67591660; called by muse, mutect2, varscan2
- LGR6 | c.1767C>T p.G589= (on ENST00000367278 / NM_001017403.1; = p.G537= on NM_021636.3) | Silent (SNP) | VAF 244/598 reads (41%) | catalogued as rs376144114; called by muse, mutect2
- TENM1 | c.2268C>T p.H756= | Silent (SNP) | VAF 102/472 reads (22%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.438C>T p.T146= | Silent (SNP) | VAF 197/801 reads (25%) | catalogued as rs754364604; called by muse, mutect2, varscan2
